CCDI case PBCGHV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c7bd3bb2-824e-4fc7-a070-0a552feb2c3b

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Cerebrum; Age at diagnosis: 1.0 years (374 days).

Biospecimens (3 samples)
- Sample 0DRIVY: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRIW6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DRIWF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
